Somatic mutation profile of cancer-model specimen HCM-CSHL-0621-C18-85M (3D Organoid, passage 12; aliquot HCM-CSHL-0621-C18-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0621-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 72.0 years (26,307 days).
Specimen HCM-CSHL-0621-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 893de626-1cda-43f4-9b85-bb7c665695fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0621-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0621-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/497071c4-8f86-4368-86c3-83a54e0d6613

The open-access MAF lists 129 somatic variants for this specimen: 99 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 26, Splice Region 4, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, 3'UTR 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 183/387 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4219G>A p.V1407I | Missense Mutation (SNP) | VAF 231/462 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs747329081; called by muse, mutect2, varscan2
- AMN | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 193/398 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as rs748210579; called by muse, mutect2, varscan2
- AOAH | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 183/388 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202089348, COSV51742780; called by muse, mutect2, varscan2
- CACNA1H | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 399/805 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs371658961; called by muse, mutect2, varscan2
- CAMK4 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 299/303 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs374581815, COSV56670305; called by muse, mutect2, varscan2
- CCDC7 | c.2261T>G p.L754R | Missense Mutation (SNP) | VAF 150/303 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1203648180; called by muse, mutect2, varscan2
- CDH17 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 189/471 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs764816423, COSV50325787; called by muse, mutect2
- CNTN1 | c.1230G>A p.A410= | Splice Region (SNP) | VAF 127/279 reads (46%) | catalogued as rs144896071; called by muse, mutect2, varscan2
- CNTN4 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 141/281 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61869771; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 152/198 reads (77%) | catalogued as rs777945397; called by mutect2, varscan2
- CRACD | c.2108G>A p.C703Y | Missense Mutation (SNP) | VAF 196/472 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.633); catalogued as rs1166805601, COSV51723387; called by muse, mutect2, varscan2
- CYLC1 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1355978822; called by muse, mutect2, varscan2
- DLL4 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 76/754 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51061532; called by muse, mutect2, varscan2
- DNAH5 | c.11987G>A p.R3996H | Missense Mutation (SNP) | VAF 160/382 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs768677731; called by muse, mutect2, varscan2
- EGFLAM | c.1113C>A p.C371* | Nonsense Mutation (SNP) | VAF 185/380 reads (49%) | catalogued as COSV59294353; called by muse, mutect2, varscan2
- ESRRB | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 257/445 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs948871827; called by muse, mutect2, varscan2
- FLT4 | c.2552T>C p.L851P | Missense Mutation (SNP) | VAF 208/421 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99987093; called by muse, mutect2, varscan2
- HOOK2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 197/419 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1455714684, COSV53402078; called by muse, mutect2, varscan2
- HOXC13 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 348/733 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV54500516; called by mutect2, varscan2
- HOXD3 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 266/571 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747637499, COSV50879425, COSV99980406; called by muse, mutect2, varscan2
- KLRB1 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 181/392 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99987374; called by muse, mutect2, varscan2
- KRT76 | c.1621A>G p.S541G | Missense Mutation (SNP) | VAF 348/785 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs372674456; called by muse, varscan2
- LLGL2 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 311/633 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs757256244, COSV51343539; called by muse, mutect2, varscan2
- MEGF11 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 273/275 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs750210212; called by muse, mutect2, varscan2
- MKI67 | c.5181G>A p.M1727I | Missense Mutation (SNP) | VAF 570/574 reads (99%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as COSV64077564; called by muse, mutect2, varscan2
- MMP16 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 164/341 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54152643; called by muse, mutect2, varscan2
- NBN | c.39A>G p.G13= | Splice Region (SNP) | VAF 143/343 reads (42%) | catalogued as rs876660470; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCOA1 | c.3045A>C p.K1015N | Missense Mutation (SNP) | VAF 271/554 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV56050803; called by muse, mutect2, varscan2
- PASD1 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 378/379 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.363); catalogued as rs144296185, COSV64854173; called by muse, mutect2, varscan2
- PCDHB14 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 257/543 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as rs782298964, COSV53391073, COSV53391754; called by muse, mutect2, varscan2
- PCDHGA12 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 233/505 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1433790348, COSV104383019; called by muse, mutect2, varscan2
- PDE6A | c.2319A>C p.Q773H | Missense Mutation (SNP) | VAF 208/400 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99678029; called by muse, mutect2, varscan2
- PDZRN4 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 211/391 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs990836428; called by muse, mutect2, varscan2
- PIK3C2A | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 237/474 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1438700912, COSV56406120; called by muse, mutect2, varscan2
- PKHD1 | c.9749C>T p.S3250L | Missense Mutation (SNP) | VAF 268/527 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61879162; called by muse, mutect2, varscan2
- POLR3H | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 192/392 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs376550737; called by muse, mutect2, varscan2
- RANBP10 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 241/490 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58162007; called by muse, varscan2
- SCARA5 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 231/510 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs774080674, COSV100108129; called by muse, mutect2, varscan2
- SCART1 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 442/918 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266745276; called by muse, mutect2, varscan2
- SCN5A | c.2436G>A p.L812= | Splice Region (SNP) | VAF 153/326 reads (47%) | catalogued as COSV100351284; called by muse, mutect2, varscan2
- SEMA3G | c.2324C>T p.T775M | Missense Mutation (SNP) | VAF 257/542 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); catalogued as rs759858543, COSV51594128; called by muse, mutect2, varscan2
- SETBP1 | c.4023A>C p.K1341N | Missense Mutation (SNP) | VAF 189/192 reads (98%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56321377; called by muse, mutect2, varscan2
- SPEG | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 455/923 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56667786; called by muse, mutect2, varscan2
- STARD8 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs373291071; called by muse, mutect2, varscan2
- SYNE1 | c.15082G>A p.A5028T (on ENST00000367255 / NM_182961.4; = p.A4957T on NM_033071.3) | Missense Mutation (SNP) | VAF 225/465 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs748882675, COSV104375152; called by muse, mutect2, varscan2
- TMEM132C | c.2797G>T p.V933L | Missense Mutation (SNP) | VAF 305/649 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59419281; called by muse, mutect2, varscan2
- TNR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 349/708 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371035988, COSV54876906; called by muse, mutect2, varscan2
- TSHZ2 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 254/806 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61591215; called by muse, mutect2, varscan2
- UNC80 | c.5893G>A p.V1965M | Missense Mutation (SNP) | VAF 203/430 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs746218899; called by muse, mutect2, varscan2
- WDR62 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 174/316 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159993236; called by muse, mutect2
- ZFP42 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 159/326 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs746841063, COSV100479168; called by muse, mutect2, varscan2
- ZNF385D | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768839606, COSV55756041, COSV99876109; called by muse, mutect2, varscan2
- ZNF879 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 187/404 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1390862090; called by muse, mutect2, varscan2
- ABCB9 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 350/708 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4009_4034del p.L1337Ifs*8 | Frame Shift Del (DEL) | VAF 351/399 reads (88%) | called by mutect2, pindel, varscan2
- ARHGDIB | c.461A>C p.E154A | Missense Mutation (SNP) | VAF 211/449 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ARHGEF5 | c.2649A>T p.Q883H | Missense Mutation (SNP) | VAF 167/514 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- BCL9L | c.834+1G>T p.X278_splice | Splice Site (SNP) | VAF 224/230 reads (97%) | called by muse, mutect2, varscan2
- BRINP3 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 141/302 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CAT | c.1154A>C p.N385T | Missense Mutation (SNP) | VAF 190/404 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); called by mutect2, varscan2
- CLIC5 | c.1190A>C p.E397A (on ENST00000185206 / NM_001370649.1; = p.E238A on NM_016929.5) | Missense Mutation (SNP) | VAF 231/463 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); called by muse, mutect2, varscan2
- COL22A1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 225/470 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CRYBG1 | c.5644C>T p.H1882Y | Missense Mutation (SNP) | VAF 238/496 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- DACT1 | c.2174A>C p.E725A | Missense Mutation (SNP) | VAF 325/664 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DHX38 | c.2696A>C p.K899T | Missense Mutation (SNP) | VAF 263/571 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXP1 | c.454del p.E152Nfs*54 | Frame Shift Del (DEL) | VAF 147/398 reads (37%) | called by mutect2, pindel, varscan2
- FSHR | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FSIP2 | c.11497T>G p.L3833V | Missense Mutation (SNP) | VAF 206/434 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRIK5 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 287/607 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- H3-3A | c.119_121del p.H40del | In Frame Del (DEL) | VAF 112/273 reads (41%) | called by mutect2, pindel, varscan2
- IFT81 | c.1358dup p.I455Yfs*5 | Frame Shift Ins (INS) | VAF 128/288 reads (44%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 227/536 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV1-9 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 227/536 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- IGLON5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 256/532 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL6R | c.1065A>G p.P355= | Splice Region (SNP) | VAF 109/284 reads (38%) | called by muse, mutect2, varscan2
- LOXL2 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 268/273 reads (98%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MLXIPL | c.707A>C p.E236A | Missense Mutation (SNP) | VAF 440/897 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMP14 | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 248/536 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MYCBP2 | c.6366A>C p.K2122N (on ENST00000357337; = p.K2160N on NM_015057.5) | Missense Mutation (SNP) | VAF 168/172 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- NUDT12 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 108/249 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PTBP3 | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.164); called by muse, mutect2
- RUNDC3A | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 205/411 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC9C2 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 197/363 reads (54%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLFN14 | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 230/510 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SSH2 | c.1361A>C p.N454T | Missense Mutation (SNP) | VAF 156/331 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- STAT5A | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 235/522 reads (45%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SVOP | c.282_282+1insCTTCG p.M95Lfs*9 | Frame Shift Ins (INS) | VAF 105/253 reads (42%) | called by pindel, varscan2
- SVOP | c.275T>A p.L92* | Nonsense Mutation (SNP) | VAF 131/286 reads (46%) | called by muse, varscan2
- TAAR2 | c.40A>T p.K14* | Nonsense Mutation (SNP) | VAF 155/345 reads (45%) | called by muse, mutect2, varscan2
- TAF1 | c.1256C>T p.S419F (on ENST00000373790 / NM_138923.4; = p.S440F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TENM3 | c.1373A>G p.E458G | Missense Mutation (SNP) | VAF 277/544 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TGM7 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 215/467 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- THOC3 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP3B | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 130/403 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP3B | c.50T>A p.I17N | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- WHRN | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 712/731 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZFAT | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 28/297 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2
- ZNF721 | c.888A>T p.E296D (on ENST00000338977; = p.E308D on NM_133474.4) | Missense Mutation (SNP) | VAF 223/450 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANO5 | c.1722C>T p.Y574= | Silent (SNP) | VAF 180/414 reads (43%) | catalogued as rs781145099, COSV61084440, COSV61090655; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOB | c.9321C>T p.N3107= | Silent (SNP) | VAF 231/501 reads (46%) | catalogued as rs72653101, COSV51936637; called by muse, mutect2, varscan2
- ATP1A4 | c.1914C>T p.G638= | Silent (SNP) | VAF 255/516 reads (49%) | catalogued as rs1446256557; called by muse, mutect2, varscan2
- ATP4A | c.331C>T p.L111= | Silent (SNP) | VAF 393/761 reads (52%) | called by muse, mutect2, varscan2
- CDH11 | c.1794C>T p.N598= | Silent (SNP) | VAF 333/674 reads (49%) | catalogued as rs563299959, COSV51764281, COSV51767424; called by muse, mutect2, varscan2
- COL19A1 | c.333C>T p.N111= | Silent (SNP) | VAF 162/309 reads (52%) | catalogued as rs143252227; called by muse, mutect2, varscan2
- COL20A1 | c.2571G>A p.A857= | Silent (SNP) | VAF 222/714 reads (31%) | catalogued as rs1170886302; called by muse, mutect2, varscan2
- COL22A1 | c.237C>T p.V79= | Silent (SNP) | VAF 340/700 reads (49%) | catalogued as rs752433406, COSV104407814; called by muse, mutect2, varscan2
- DOCK3 | c.1977C>T p.Y659= | Silent (SNP) | VAF 145/308 reads (47%) | catalogued as rs1394354143, COSV56512666; called by muse, mutect2, varscan2
- DOK7 | c.174G>A p.T58= | Silent (SNP) | VAF 293/569 reads (51%) | catalogued as COSV100403213, COSV60772701; called by muse, mutect2, varscan2
- GBX1 | c.24C>T p.S8= | Silent (SNP) | VAF 172/403 reads (43%) | called by muse, mutect2, varscan2
- ITGAX | c.750C>T p.A250= | Silent (SNP) | VAF 259/451 reads (57%) | catalogued as rs775201614; called by muse, mutect2, varscan2
- JAML | c.390G>A p.A130= (on ENST00000356289 / NM_001098526.2; = p.A120= on NM_153206.3) | Silent (SNP) | VAF 165/172 reads (96%) | catalogued as rs774361136; called by muse, mutect2, varscan2
- MRPL24 | c.261C>T p.V87= | Silent (SNP) | VAF 135/340 reads (40%) | catalogued as rs749229582, COSV61975520; called by muse, mutect2, varscan2
- NRXN2 | c.624C>T p.P208= | Silent (SNP) | VAF 247/250 reads (99%) | called by muse, mutect2, varscan2
- PCDH7 | c.6G>A p.L2= | Silent (SNP) | VAF 232/469 reads (49%) | called by muse, mutect2, varscan2
- PDZD4 | c.1635C>T p.R545= | Silent (SNP) | VAF 486/490 reads (99%) | catalogued as rs1361920534; called by muse, varscan2
- SI | c.5328G>A p.G1776= | Silent (SNP) | VAF 199/418 reads (48%) | catalogued as rs1020747413; called by muse, mutect2, varscan2
- SLC16A13 | c.672C>T p.T224= | Silent (SNP) | VAF 245/579 reads (42%) | catalogued as COSV100338610; called by muse, mutect2, varscan2
- SLC9A4 | c.426C>T p.G142= | Silent (SNP) | VAF 353/731 reads (48%) | catalogued as rs575529823, COSV54828670, COSV54837751; called by muse, mutect2, varscan2
- SOX3 | c.654C>A p.L218= | Silent (SNP) | VAF 366/369 reads (99%) | called by muse, mutect2, varscan2
- SYCN | c.234C>T p.S78= | Silent (SNP) | VAF 371/760 reads (49%) | called by muse, mutect2, varscan2
- TAF1L | c.5364T>G p.A1788= | Silent (SNP) | VAF 318/658 reads (48%) | called by muse, mutect2, varscan2
- TM7SF3 | c.669G>A p.Q223= | Silent (SNP) | VAF 133/296 reads (45%) | called by muse, mutect2, varscan2
- TUBB1 | c.1059C>G p.V353= | Silent (SNP) | VAF 277/913 reads (30%) | called by muse, mutect2, varscan2
- TUBB4B | c.906C>T p.A302= | Silent (SNP) | VAF 374/381 reads (98%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.989-209G>A | Intron (SNP) | VAF 380/773 reads (49%) | called by muse, mutect2, varscan2
- CCPG1 | c.*3091C>T | 3'UTR (SNP) | VAF 156/316 reads (49%) | called by muse, mutect2, varscan2
- PIDD1 | c.1303-136G>A | Intron (SNP) | VAF 198/428 reads (46%) | catalogued as rs574433149; called by muse, mutect2
- SLITRK4 | c.*295A>G | 3'UTR (SNP) | VAF 190/190 reads (100%) | called by muse, mutect2, varscan2
